CPTAC case C3L-01663 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7a1dfdd0-effb-4ade-ae0c-a7a0892c778d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Dead; Days to death: 1,729 days (4.7 years); Year of death: 2021; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 73.6 years (26,868 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,729 days (4.7 years); Progression or recurrence: yes; Days to last follow up: 1,723 days (4.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 1.6 cm (a second GDC size field records 16 cm); Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 18; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 358 days; Disease response: Tumor Free.
- Days to follow up: 688 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,072 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,428 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 1,428 days (3.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 1,204 days (3.3 years).
- Days to follow up: 1,723 days (4.7 years); Disease response: With Tumor; ECOG performance status: 5.

Other clinical attributes
- Weight: 57 kg; Height: 165 cm; BMI: 20.94.

Exposures
- Tobacco smoking status: Current Smoker; Cigarettes per day: 20; Alcohol history: Yes; Alcohol intensity: Heavy Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01663-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 207 mg.
- Sample C3L-01663-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 203 mg; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01663-22: Section location: Right Upper Lobe; Percent tumor nuclei: 70; Percent necrosis: 10.
- Sample C3L-01663-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 391 mg; Time between excision and freezing: 13 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01663-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
